Gene-level copy-number profile of tumor specimen TCGA-34-2605-01A from TCGA case TCGA-34-2605, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 76.2 years (27,833 days).
Specimen TCGA-34-2605-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.e2bdb93a-21c8-4e9b-adf5-9d0cb85a87b0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-34-2605-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/00a1cde7-a4e1-40b0-8110-970f2d3847a6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 3,401; copy number 2: 26,612; copy number 3: 17,858; copy number 4: 8,633; copy number 5: 918; copy number 6: 1,458; copy number 7: 54; copy number 8: 85; copy number 9: 116; copy number 10: 605; copy number 11: 28; copy number 14: 23; copy number 17: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-34-2605-01A-01D-0844-01): tumor purity 0.36, ploidy 4.6, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,294 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,336,446–63,197,037, 77 genes, copy number 5–17 (broad region; genes not listed).
- chr2:63,168,600–63,233,577, 2 genes, copy number 5: Metazoa_SRP, MTFR2P1.
- chr2:81,418,723–82,866,508, 17 genes, copy number 6: CHMP4AP1, LINC01815, RNA5SP99, AC013262.1, RN7SL201P, AC079896.1, LYARP1, RNU6-685P, Y_RNA, AC010105.1, RBX1P1, MTND4P25, MTND5P27, MTND6P7, MTCYBP7, AC098817.1, DHFRP3.
- chr2:175,842,887–178,142,651, 72 genes, copy number 6 (broad region; genes not listed).
- chr2:183,607,442–186,509,361, 25 genes, copy number 6 (within-gene range 2–6): CACYBPP2, AC093639.3, AC093639.1, AC093639.2, AC096555.1, AC020584.1, MIR548AE1, AC096667.1, ZNF804A, RPL23AP33, AC009315.1, ELF2P4, FSIP2-AS1, U8, FSIP2-AS2, FSIP2, AC097500.1, RPL21P32, LINC01473, AC104058.1, RPL23AP35, AC017071.1, MED28P3, ZC3H15, DPRXP1.
- chr3:93,843,764–97,975,056, 36 genes, copy number 6: RNU6-488P, PROS1, Y_RNA, RNU6-511P, ARL13B, HMGN1P7, STX19, DHFR2, NSUN3, RBBP4P2, ARMC10P1, AC140059.1, WDR82P1, LINC00879, RPS18P6, MTHFD2P1, AC106719.1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, AC109782.1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, AC026100.1.
- chr3:140,865,075–198,222,513, 1,003 genes, copy number 6–10 (broad region; genes not listed).
- chr6:42,499,710–65,707,226, 334 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr6:134,897,874–136,792,477, 38 genes, copy number 5 (within-gene range 3–5): MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1, RN7SKP299, AL024508.1, MAP3K5, MAP3K5-AS1, RNA5SP219.
- chr7:56,228,634–67,362,950, 297 genes, copy number 5 (broad region; genes not listed).
- chr7:143,047,213–148,420,998, 93 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:564,296–34,166,954, 832 genes, copy number 6–8 (broad region; genes not listed).
- chr15:19,878,555–22,617,854, 139 genes, copy number 5 (broad region; genes not listed).
- chr19:34,092,561–40,215,575, 329 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,192. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
